Somatic mutation profile of tumor specimen TCGA-13-1505-01A (aliquot TCGA-13-1505-01A-01W-0545-08) from TCGA case TCGA-13-1505, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-13-1505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76fcb2e1-223b-4ad9-a3e8-bf06f73e0c84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1505-10A (Blood Derived Normal), aliquot TCGA-13-1505-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff0faef-6cca-4d6c-89e6-27d4f2b1c299

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV57530754; called by muse, mutect2, varscan2
- ASPM | c.7340C>A p.A2447D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV99660510; called by muse, mutect2, varscan2
- B4GALT6 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 75/752 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as COSV99380086; called by muse, mutect2
- CD82 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1339483186, COSV57036117; called by muse, mutect2
- CEACAM5 | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55753544; called by muse, mutect2, varscan2
- ELF4 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1220135107, COSV57453833; called by muse, mutect2, varscan2
- HUNK | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV54226978; called by muse, mutect2, varscan2
- ITK | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 80/453 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV68435396; called by muse, mutect2, varscan2
- MED13L | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV99929040; called by muse, mutect2, varscan2
- MYADM | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV61240389; called by muse, mutect2, varscan2
- PARD6A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV54669113; called by muse, mutect2, varscan2
- PLD2 | c.1613_1614del p.M538Tfs*102 | Frame Shift Del (DEL) | VAF 20/31 reads (65%) | catalogued as COSV54007787; called by mutect2, pindel, varscan2
- PPP1R3A | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99493100; called by muse, mutect2, varscan2
- PTPRH | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV54744904, COSV54747853; called by muse, mutect2
- TP53 | c.225del p.A76Hfs*47 | Frame Shift Del (DEL) | VAF 14/16 reads (88%) | catalogued as COSV53328406; called by mutect2, varscan2
- TPH2 | c.947C>G p.T316R | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61593139; called by muse, varscan2
- TTN | c.98857C>T p.R32953C (on ENST00000591111; = p.R25529C on NM_003319.4) | Missense Mutation (SNP) | VAF 92/620 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs879240376, COSV60202286; called by muse, mutect2, varscan2
- TTN | c.55477T>A p.S18493T (on ENST00000591111; = p.S11069T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | PolyPhen benign (0.005); catalogued as rs904878126, COSV60202298; called by muse, mutect2, varscan2
- ZNF681 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | catalogued as COSV101267481, COSV68075515; called by muse, mutect2
- CD163 | c.1801C>A p.L601I | Missense Mutation (SNP) | VAF 12/389 reads (3%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KHDRBS2 | c.336+2T>C p.X112_splice | Splice Site (SNP) | VAF 10/320 reads (3%) | called by muse, mutect2
- PCM1 | c.3650G>T p.G1217V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SHTN1 | c.607T>C p.C203R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT4 | c.3411T>C p.Y1137= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV67893930; called by muse, mutect2, varscan2
- FAT4 | c.10245C>A p.I3415= | Silent (SNP) | VAF 37/255 reads (15%) | catalogued as COSV58698292; called by muse, mutect2, varscan2
- HTT | c.5850C>T p.S1950= | Silent (SNP) | VAF 89/327 reads (27%) | catalogued as rs201305332; called by muse, mutect2, varscan2
- MUC16 | c.12921G>A p.Q4307= | Silent (SNP) | VAF 14/358 reads (4%) | catalogued as COSV101200118; called by muse, mutect2
- PTPRF | c.2409G>A p.K803= | Silent (SNP) | VAF 22/587 reads (4%) | catalogued as COSV100740962; called by muse, mutect2
- SSX6P | n.74C>T | RNA (SNP) | VAF 75/203 reads (37%) | catalogued as rs150874433; called by muse, mutect2, varscan2
- TTN | c.10361-3808_10361-3806dup | Intron (INS) | VAF 38/206 reads (18%) | called by mutect2, varscan2
